MMRF case MMRF_1152 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/43967950-7bb0-4de4-a20a-635001c80aa5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.0 years (24,476 days); ISS stage: III; Days to last known disease status: 1,705 days (4.7 years); Days to last follow up: 1,705 days (4.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 192 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 108 days; Days to treatment end: 192 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 304 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 2): M Protein 9.7 g/dL; Immunoglobulin G 3.37 g/L; Immunoglobulin A 57.8 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 7.67 µg/mL; Hemoglobin 5.39 mmol/L; Leukocytes 2.75 ×10⁹/L; Creatinine 203 µmol/L; Blood Urea Nitrogen 12.1 mmol/L; Calcium 2.55 mmol/L; Albumin 20 g/L; Total Protein 9.2 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.05 mg/dL.
- Day 81 (ECOG 1): M Protein 2.75 g/dL; Hemoglobin 7.19 mmol/L; Leukocytes 4.4 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 8.8 g/dL; Glucose 6.66 mmol/L.
- Day 165 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Hemoglobin 7.94 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.94 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 6 mmol/L.
- Day 271 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 333: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Beta 2 Microglobulin 2.45 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.16 mmol/L.
- Day 529 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Hemoglobin 8.8 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.82 mmol/L.
- Day 641 (ECOG 1): M Protein 0 g/dL; Hemoglobin 7.32 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 104 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.39 mmol/L.
- Day 711 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Beta 2 Microglobulin 2.41 µg/mL; Lactate Dehydrogenase 3.58 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.73 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.45 mmol/L.
- Day 795 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 9.45 g/L; Beta 2 Microglobulin 2.34 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.06 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 8.91 mmol/L.
- Day 857 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.82 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 2.89 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.68 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 3.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 9.41 mmol/L.
- Day 985: Hemoglobin 8.49 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.17 ×10⁹/L; Platelets 212 ×10⁹/L; Glucose 7.92 mmol/L.
- Day 1,117 (ECOG 1): Hemoglobin 8.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 7.48 mmol/L.
- Day 1,201 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Beta 2 Microglobulin 3.92 µg/mL; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.82 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.94 mmol/L.
- Day 1,285 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 3.46 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 2.93 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.82 mmol/L.
- Day 1,357: Hemoglobin 8.62 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.81 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 1,503 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 3.84 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.55 mmol/L.
- Day 1,607 (ECOG 1): Hemoglobin 8.31 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 153 ×10⁹/L.
- Day 1,705: Immunoglobulin G 10.7 g/L; Immunoglobulin A 3.47 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 6.6 mmol/L.

Other clinical attributes
- Day -2: Weight: 97 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (2 samples)
- Sample MMRF_1152_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1152_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
